Surgical pathology report (de-identified scan), TCGA case TCGA-A2-A04Y, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Walter Reed, specimen TCGA-A2-A04Y-01A (Primary Tumor).

[page 1 of 4]
1CB-0-3
Carcinoma, infiltrating ductal, NOS 8500/3
Site: breast, NOS C50.9 1/24/11 for

FOR OFFICIAL USE ONLY - PERSONAL DATA - PRIVACY ACT OF 1974

SURGICAL PATHOLOGY REPORT

Patient:
FMP/SSN:
DOB/Age/Sex:
Location:
Physician(s):
Race: **WHITE**
Specimen #:
Taken:
Received:
Reported:

SPECIMEN:

A: RIGHT BREAST B: RIGHT SENTINEL LYMPH NODE #1
C: LEFT BREAST D: LEFT SENTINEL LYMPH NODE

FINAL DIAGNOSIS:

A&B. RIGHT BREAST, SIMPLE MASTECTOMY AND SENTINEL NODE BIOPSY:

- TUMOR TYPE: INFILTRATING DUCTAL CARCINOMA.
- NOTTINGHAM GRADE: POORLY DIFFERENTIATED (G3).
- NOTTINGHAM SCORE: 8/9
(Tubules = 3, Nuclei = 3, Mitoses = 2).
- TUMOR SIZE (GREATEST DIMENSION): 2.5 CM, MEASURED GROSSLY.
- TUMOR NECROSIS: ABSENT.
- MICROCALCIFICATIONS: PRESENT, IN BENIGN LESION.
- VENOUS / LYMPHATIC INVASION: PRESENT.
- MARGINS: NEGATIVE.
- DISTANCE OF TUMOR FROM NEAREST MARGIN IS 0.3 CM, FROM SUPERFICIAL / SKIN MARGIN; 5.0 CM FROM DEEP MARGIN.
- INTRADUCTAL COMPONENT: ABSENT.
- LYMPH NODE: 1 OF 1 POSITIVE FOR MICROSCOPIC FOCUS OF TUMOR (0.47 MM); PRESENT WITHIN SUBCAPSULAR SINUS.
- NIPPLE INVOLVEMENT: ABSENT.
- SKIN INVOLVEMENT: ABSENT.
- MULTICENTRICITY: ABSENT.
- HORMONE RECEPTORS
- ESTROGEN RECEPTOR: POSITIVE (90%)
- PROGESTERONE RECEPTOR: POSITIVE (10%)
- HER2: NEGATIVE (BY IMMUNOSTAINS AND FISH).
- ADDITIONAL PATHOLOGIC CHANGES: FIBROADENOMA, WITH CALCIFICATION.

C&D. LEFT BREAST, SIMPLE MASTECTOMY AND SENTINEL NODE BIOPSY:

- TUMOR TYPE: INFILTRATING DUCTAL CARCINOMA.
- NOTTINGHAM GRADE: POORLY DIFFERENTIATED (G3).
- NOTTINGHAM SCORE: 9/9
(Tubules = 3, Nuclei = 3, Mitoses = 3).
- TUMOR SIZE (GREATEST DIMENSION): 5.0 CM, MEASURED GROSSLY.
- TUMOR NECROSIS: ABSENT.
- MICROCALCIFICATIONS: ABSENT.
- VENOUS / LYMPHATIC INVASION: ABSENT.

[page 2 of 4]
SURGICAL PATHOLOGY REPORT

Patient:

Specimen #:

FINAL DIAGNOSIS (continued):

- MARGINS: NEGATIVE
- DISTANCE OF TUMOR FROM NEAREST MARGIN IS 0.3 CM FROM SUPERFICIAL / SKIN MARGIN; 1.0 CM FROM THE DEEP MARGIN.
- INTRADUCTAL COMPONENT: ABSENT.
- LYMPH NODES: ONE LYMPH NODE, NEGATIVE BY ROUTINE AND IMMUNO STAINS.
- NIPPLE INVOLVEMENT: ABSENT.
- SKIN INVOLVEMENT: ABSENT.
- MULTICENTRICITY: ABSENT.
- HORMONE RECEPTORS (PREPARED ON :
- ESTROGEN RECEPTOR: POSITIVE (NEARLY 100%)
- PROGESTERONE RECEPTOR: POSITIVE (40%)
- HER2: POSITIVE (3+ ON IHC, POSITIVE BY FISH).
- ADDITIONAL PATHOLOGIC CHANGES: FIBROADENOMA.

COMMENT: The lesion from the right side would be stage pT2 N1mi MX;
the lesion from the left side would be stage pT2 N0(i-) MX.

** Report Electronically Signed Out **

=====

CLINICAL DIAGNOSIS AND HISTORY:

Bilateral breast cancer.

GROSS DESCRIPTION:

A. Received fresh labeled with the patient's name designated "RIGHT BREAST" consists of a 1134 gram mastectomy specimen oriented with a short stitch superior and a long stitch lateral. The specimen measures 27 cm medial to lateral, 21 cm superior to inferior and 4.5 cm superficial to deep. The lightly pigmented superficial skin ellipse measure 6.0 x 3.5 cm and displays a 1.0 cm centrally located, everted nipple free of discharge. The deep margin is inked black and a portion of superficial margin is inked blue. Serial sections reveal a 2.5 x 1.5 x 1.0 cm well circumscribed pink white mass located in the upper mid breast. The mass comes to within 0.3 cm of the inked superficial margin and is located 5 cm from the deep margin. Located in the lower outer quadrant is a 1.0 x 0.7 x 0.7 cm well circumscribed markedly calcified nodule (consistent with a calcified fibroadenoma). The remainder of the breast is predominantly composed of lobulated yellow tan adipose tissue admixed with unremarkable fibrous tissue. No additional lesions are identified. No lymph nodes are

[page 3 of 4]
SURGICAL PATHOLOGY REPORT

Patient:

Specimen #:

GROSS DESCRIPTION (continued):

identified. Sections are submitted as follows:

A1: skin
A2: mass
A3-A4: mass with superficial margin
A5: upper outer quadrant
A6: lower outer quadrant
A7: central
A8: lower inner quadrant
A9: upper inner quadrant
A10: nipple
A11: upper outer quadrant
A12: lower outer quadrant with calcified nodule
A13: lower inner quadrant
A14: upper inner quadrant.
Matched section of A1, A2 and A6-A9 are preserved in OCT for CBCP protocol.

B. Received fresh labeled with the patient's name designated "SENTINEL NODE #1 RIGHT SIDE" consists of a 2.4 x 2.0 x 0.8 cm irregular portion of soft tissue. Sectioning reveals 2.0 x 1.0 x 0.5 cm pink tan lymph node. The lymph node is unevenly bisected. The specimen is entirely submitted as follows:

B1: lymph node

B2: adipose tissue.

A matched section of B1 is submitted in OCT for CBCP protocol.

C. Received fresh labeled with the patient's name designated "LEFT BREAST" consists of a 1321 gram mastectomy specimen oriented with a short stitch superior and long lateral. The specimen measures 28.0 cm superior to inferior, 23 cm medial to lateral, and 4.0 cm anterior to posterior. The lightly pigmented superficial skin ellipse measures 7.0 x 4.0 cm and displays a 1.0 cm centrally located everted nipple. Scattered irregular portions of red brown muscle are noted on deep resection margin. The deep margin is inked black and a portion of superficial margin is inked blue. Serial sections reveal a well circumscribed gritty pink tan mass involving the upper mid and upper inner quadrant of the breast. The mass measures 5.0 x 4.2 x 2.7 cm and is located 3.0 cm from deep margin and 0.2 cm from superficial surface. Located 1.0 cm from the mass, within the central portion of the breast, is a 1.0 cm tan white rubbery nodule consistent with a fibroadenoma. The remainder of the breast is composed of lobulated yellow tan adipose tissue

[page 4 of 4]
SURGICAL PATHOLOGY REPORT

Patient:

Specimen #:

GROSS DESCRIPTION (continued):

admixed with a small amount of tan white fibrous tissue. No additional lesions are identified. No lymph nodes are identified. Sections are submitted as follows:

- C1: skin
- C2: mass
- C3: mass with superficial margin
- C4: mass
- C5: upper inner quadrant
- C6: lower inner quadrant
- C7: central nodule
- C8: lower outer quadrant
- C9: upper outer quadrant
- C10: nipple
- C11: upper inner quadrant
- C12: lower inner quadrant
- C13: lower outer quadrant
- C14: upper outer quadrant.

Matched sections of C1-C2 and C4-C9 are submitted in OCT for CBCP protocol.

D. Received fresh labeled with the patient's name designated "LEFT SIDE SENTINEL NODE #1" consists of a 2.5 x 2.0 x 0.5 cm irregular portion of soft tissue. The specimen is bisected to reveal a 1.7 x 1.0 x 0.5 cm pink tan lymph node. The specimen is entirely submitted in D1. A matched section of D1 is submitted in OCT for CBCP protocol.

Source: NCI Genomic Data Commons file 4751f5a1-72c0-4720-9f4f-f63ea87b3e00 (TCGA-A2-A04Y.E4F7064C-9D81-49B5-9992-898155B3F11E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).